Somatic mutation profile of tumor specimen MP2PRT-PAVTPM-TMP1-A (aliquot MP2PRT-PAVTPM-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVTPM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,473 days).
Specimen MP2PRT-PAVTPM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ac3efbd-d722-4b56-843c-d619df0c3d6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTPM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTPM-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79c0562a-71aa-48c1-b11e-ec2bea3464a6

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKS4B | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 110/291 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs777559520; called by muse, mutect2, varscan2
- C1orf105 | c.407-1G>C p.X136_splice | Splice Site (SNP) | VAF 41/149 reads (28%) | catalogued as COSV100877962; called by muse, mutect2, varscan2
- IKZF3 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 143/362 reads (40%) | catalogued as COSV53100823; called by muse, mutect2, varscan2
- MX1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); catalogued as rs922135425, COSV55817601; called by muse, mutect2, varscan2
- OIT3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 122/369 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); catalogued as rs144661264, COSV104395920; called by muse, mutect2, varscan2
- OR4K2 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53848214; called by muse, mutect2, varscan2
- SIN3A | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 107/319 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); catalogued as COSV64583257; called by muse, mutect2, varscan2
- SPRED1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 97/296 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1345810751, COSV54438084; called by muse, mutect2, varscan2
- ZNF681 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as rs1328385642; called by muse, mutect2, varscan2
- MLXIPL | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 14/388 reads (4%) | called by muse, mutect2
- MTUS2 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- NAV3 | c.2838dup p.P947Tfs*6 | Frame Shift Ins (INS) | VAF 54/228 reads (24%) | called by mutect2, pindel, varscan2
- OBSCN | c.22628G>A p.G7543E | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- RPTN | c.224T>A p.L75H | Missense Mutation (SNP) | VAF 109/320 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- THEGL | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 234/652 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.063); called by muse, mutect2
- ZC3H12B | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 110/415 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDPD2 | c.735G>A p.R245= | Silent (SNP) | VAF 91/303 reads (30%) | called by muse, mutect2, varscan2
- ITGAM | c.3108G>A p.P1036= (on ENST00000648685 / NM_001145808.2; = p.P1035= on NM_000632.4) | Silent (SNP) | VAF 30/378 reads (8%) | catalogued as rs1465981481; called by muse, mutect2
- KAT2A | c.1452G>A p.A484= | Silent (SNP) | VAF 116/312 reads (37%) | catalogued as rs782360789; called by muse, mutect2, varscan2
- RAB5C | c.177C>G p.L59= | Silent (SNP) | VAF 67/217 reads (31%) | called by muse, mutect2, varscan2
- STON1 | c.186C>G p.L62= | Silent (SNP) | VAF 12/409 reads (3%) | called by muse, mutect2
- TRIM32 | c.27G>C p.L9= | Silent (SNP) | VAF 60/199 reads (30%) | catalogued as rs201891227; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MAGEC3 | c.1729-22G>A | Intron (SNP) | VAF 182/492 reads (37%) | catalogued as rs867668673; called by muse, mutect2, varscan2
